Somatic mutation profile of tumor specimen TCGA-DK-A2HX-01A (aliquot TCGA-DK-A2HX-01A-12D-A18F-08) from TCGA case TCGA-DK-A2HX, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 80.3 years (29,332 days).
Specimen TCGA-DK-A2HX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc04d0e2-157c-43b8-a3c6-e1cd2dfd885a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A2HX-10A (Blood Derived Normal), aliquot TCGA-DK-A2HX-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e88087b-329b-4a61-806d-f507ba40a655

The open-access MAF lists 111 somatic variants for this specimen: 85 protein-altering or splice-affecting, 25 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 25, Nonsense Mutation 9, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1, Nonstop Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN3 | c.2506G>C p.E836Q | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV59748646; called by muse, mutect2
- ADD3 | c.1851G>C p.K617N (on ENST00000356080 / NM_001320591.2; = p.K585N on NM_001121.4) | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.111); catalogued as rs1404811559, COSV53322364; called by muse, mutect2, varscan2
- ADGRB2 | c.2074G>A p.V692M | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as COSV57073647; called by muse, mutect2, varscan2
- AKAP11 | c.5257C>T p.H1753Y | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs1224929992, COSV50295777; called by muse, mutect2, varscan2
- AL035460.1 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV63028108; called by muse, mutect2
- ANKFN1 | c.617G>T p.S206I | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV59447314; called by mutect2, varscan2
- ARHGAP20 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV52811192; called by muse, mutect2, varscan2
- ARID1A | c.3598C>T p.Q1200* | Nonsense Mutation (SNP) | VAF 27/59 reads (46%) | catalogued as COSV61375497; called by muse, mutect2, varscan2
- ARMC12 | c.717C>G p.F239L (on ENST00000373866 / NM_001286574.2; = p.F266L on NM_145028.5) | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV55360163; called by muse, mutect2
- BECN1 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.983); catalogued as rs765239824, COSV64120830; called by muse, mutect2, varscan2
- CAMTA2 | c.1088A>G p.E363G | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as COSV61834917; called by muse, mutect2, varscan2
- CEP41 | c.927G>C p.K309N | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as COSV56219592; called by muse, mutect2, varscan2
- CHD2 | c.4291G>T p.D1431Y | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV67709351; called by muse, mutect2
- CLPX | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV55644535; called by muse, mutect2, varscan2
- CLVS2 | c.507C>A p.F169L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV51562595, COSV51566926; called by muse, mutect2, varscan2
- CNTN4 | c.1992G>C p.L664F | Missense Mutation (SNP) | VAF 12/333 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61872993; called by muse, mutect2
- COG8 | c.252C>G p.F84L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV54742354; called by muse, mutect2, varscan2
- CPM | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104405407, COSV58033274; called by muse, mutect2, varscan2
- CRYBB2 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as CM162359, COSV101236725; called by muse, mutect2, varscan2
- DGKK | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs1557234490; called by muse, varscan2
- DNAH7 | c.10345G>A p.D3449N | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.524); catalogued as COSV56764921; called by muse, mutect2, varscan2
- FARSB | c.1532T>C p.I511T | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV56049606; called by muse, mutect2, varscan2
- FGFR2 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.394); catalogued as rs189010277, COSV60646974; called by muse, mutect2, varscan2
- FREM1 | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as COSV66523561; called by muse, mutect2, varscan2
- GAPT | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV59246946, COSV59247278; called by muse, mutect2, varscan2
- GJA9 | c.989C>G p.S330C | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as COSV100668177, COSV62532158; called by muse, mutect2
- KAT7 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV52014489; called by muse, mutect2, varscan2
- KITLG | c.287G>T p.S96I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV57201462; called by muse, mutect2, varscan2
- KMT2C | c.9638C>T p.S3213L | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100079309, COSV51288409, COSV51482938; called by muse, mutect2
- LAMA2 | c.4888G>A p.E1630K | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.798); catalogued as rs774435152, COSV70347144; called by muse, mutect2, varscan2
- LAS1L | c.814C>A p.L272M | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV56707339; called by muse, mutect2, varscan2
- LMCD1 | c.723+1G>A p.X241_splice | Splice Site (SNP) | VAF 6/16 reads (38%) | catalogued as rs1170461678, COSV99337770; called by muse, mutect2, varscan2
- LRP1 | c.10772G>T p.R3591L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV54511166, COSV54526982; called by muse, mutect2
- LRP12 | c.1882G>A p.V628I | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52628824; called by muse, mutect2, varscan2
- LRRIQ3 | c.1116G>T p.E372D | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.107); catalogued as rs1303285355, COSV63043846, COSV63046524; called by muse, mutect2, varscan2
- MINK1 | c.3502G>T p.D1168Y | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563737153, COSV53417976; called by muse, mutect2
- MOCOS | c.1685G>A p.R562K | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV54343398; called by muse, mutect2
- MUC16 | c.1103A>G p.H368R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs527935365, COSV67465704; called by muse, mutect2, varscan2
- NBN | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55370899; called by muse, mutect2
- NEK11 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.902); catalogued as COSV63579536, COSV63580876; called by muse, mutect2, varscan2
- NFX1 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs1384067072, COSV59310319; called by muse, mutect2, varscan2
- NLRP8 | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 25/84 reads (30%) | catalogued as COSV52583255; called by muse, mutect2, varscan2
- NRG1 | c.954C>G p.I318M (on ENST00000405005 / NM_013964.5; = p.I323M on NM_013956.5) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.377); catalogued as COSV55159393, COSV99827852; called by muse, mutect2, varscan2
- NRG4 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.957); catalogued as COSV67530371; called by muse, mutect2, varscan2
- OTP | c.316C>A p.R106S | Missense Mutation (SNP) | VAF 86/177 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV60568848, COSV60569769; called by muse, mutect2, varscan2
- PCBP1 | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.408); catalogued as rs1443310840, COSV57850481; called by muse, mutect2, varscan2
- PCDHA11 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs782499527, COSV56477470; called by muse, mutect2, varscan2
- PI15 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52641441, COSV52643661; called by muse, mutect2, varscan2
- PIBF1 | c.1907G>C p.R636T | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1488002865, COSV58323044; called by muse, mutect2
- PLA2G2E | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV64290508; called by muse, mutect2, varscan2
- POC5 | c.1314G>T p.M438I (on ENST00000428202 / NM_001099271.2; = p.M413I on NM_152408.2) | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV66842283; called by muse, mutect2, varscan2
- POGZ | c.3005G>A p.R1002H | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as rs772614527, COSV51850204; called by muse, mutect2, varscan2
- PPFIA4 | c.1463G>A p.R488H (on ENST00000447715; = p.R463H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as rs907804074, COSV55314996; called by muse, mutect2, varscan2
- PTPN14 | c.1359G>C p.K453N | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65284039; called by muse, mutect2, varscan2
- PTPRF | c.3304C>T p.H1102Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.087); catalogued as rs1340394688, COSV63444950; called by muse, mutect2, varscan2
- RBM26 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV57394497, COSV57401221; called by muse, mutect2
- RRP12 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs1564766189, COSV59667516; called by muse, mutect2, varscan2
- RSPH6A | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); catalogued as COSV55571751; called by muse, mutect2, varscan2
- SCGB2B2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.621); catalogued as COSV64857179; called by muse, mutect2
- SFXN2 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 40/121 reads (33%) | catalogued as rs756234076; called by muse, mutect2, varscan2
- SH3D19 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 15/231 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.475); catalogued as COSV58790618; called by muse, mutect2
- SLC39A12 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66198199; called by muse, mutect2
- SMARCA4 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.73); catalogued as rs1568416700, COSV60794306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPEG | c.3976G>A p.V1326M | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as rs1438556859, COSV56668767; called by muse, mutect2, varscan2
- SPHK2 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs1458427766, COSV55337351; called by muse, mutect2, varscan2
- SPTA1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.474); catalogued as COSV63753038; called by muse, mutect2, varscan2
- SRARP | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs767345951, COSV61497784; called by muse, mutect2, varscan2
- SRD5A2 | c.650C>A p.A217E | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51871582; called by muse, mutect2, varscan2
- TMEM215 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV61363445; called by muse, mutect2, varscan2
- UBQLN2 | c.611T>C p.L204P | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100592600, COSV57739588; called by muse, mutect2, varscan2
- USP26 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.677); catalogued as COSV63708707; called by muse, mutect2, varscan2
- ADAMTS9 | c.3491C>A p.S1164* | Nonsense Mutation (SNP) | VAF 19/103 reads (18%) | called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6872C>G p.S2291* | Nonsense Mutation (SNP) | VAF 13/210 reads (6%) | called by muse, mutect2
- CDKN1A | c.110dup p.M38Nfs*10 | Frame Shift Ins (INS) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- CDKN1A | c.249_262del p.R84Vfs*40 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel
- DDR1 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2
- DHX9 | c.1711C>T p.Q571* | Nonsense Mutation (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- GDF15 | c.926G>C p.*309Sext*41 | Nonstop Mutation (SNP) | VAF 19/106 reads (18%) | called by muse, mutect2, varscan2
- KIR2DL3 | c.644C>A p.P215Q | Missense Mutation (SNP) | VAF 89/419 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- LRBA | c.5375C>G p.S1792* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- PRAMEF20 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- RYR2 | c.3310G>T p.E1104* | Nonsense Mutation (SNP) | VAF 28/159 reads (18%) | called by muse, mutect2, varscan2
- SH3D19 | c.695-1G>A p.X232_splice | Splice Site (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2
- SMC4 | c.1741C>T p.Q581* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- XAGE2 | c.153G>C p.K51N | Missense Mutation (SNP) | VAF 19/286 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.37); called by muse, mutect2
- ASMTL | c.360C>T p.S120= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as rs764521333, COSV67243009; called by muse, mutect2
- ATP10D | c.3747G>A p.K1249= | Silent (SNP) | VAF 17/150 reads (11%) | catalogued as COSV56707122; called by muse, mutect2, varscan2
- ATRAID | c.784C>T p.L262= (on ENST00000611786; = p.L149= on NM_016085.5) | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as rs777813903, COSV53026820; called by muse, mutect2, varscan2
- CA5A | c.69C>A p.L23= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV59239991, COSV59240644; called by muse, mutect2
- CDH20 | c.534C>T p.S178= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV53009790; called by muse, mutect2, varscan2
- COL6A1 | c.2997C>T p.G999= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as rs780912204, COSV62612834; called by muse, mutect2, varscan2
- DENND4A | c.3132C>T p.L1044= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV71265790; called by muse, mutect2
- DHRS7 | c.408C>T p.V136= | Silent (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2
- DMD | c.6360A>G p.L2120= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV63754960; called by muse, mutect2, varscan2
- DNAJC16 | c.648C>T p.P216= | Silent (SNP) | VAF 35/60 reads (58%) | catalogued as rs535795316, COSV65448529; called by muse, mutect2, varscan2
- GATAD2A | c.1764C>A p.L588= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV53069960; called by muse, mutect2, varscan2
- ITPRIP | c.181C>A p.R61= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as COSV53390563, COSV53391516; called by muse, mutect2, varscan2
- KITLG | c.288T>C p.S96= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV57201454; called by muse, mutect2, varscan2
- LHX9 | c.522C>T p.F174= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs767031663, COSV61328715; called by muse, mutect2, varscan2
- MAD1L1 | c.486G>A p.L162= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV56234457; called by muse, mutect2, varscan2
- MAST4 | c.4596G>A p.L1532= (on ENST00000403625 / NM_001164664.2; = p.L1343= on NM_015183.3) | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV55117832; called by muse, mutect2
- ODF2 | c.894G>A p.A298= (on ENST00000434106 / NM_153433.2; = p.A274= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as rs150687097; called by mutect2, varscan2
- RIN3 | c.2325C>T p.L775= | Silent (SNP) | VAF 11/136 reads (8%) | catalogued as rs371867600, COSV53653411; called by muse, mutect2
- RXFP3 | c.1110G>A p.A370= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV57505551; called by muse, mutect2, varscan2
- SCYL2 | c.2088G>A p.L696= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV62568790; called by muse, mutect2
- SPTA1 | c.5799C>T p.F1933= | Silent (SNP) | VAF 32/179 reads (18%) | catalogued as COSV63753035; called by muse, mutect2, varscan2
- TAAR1 | c.807C>A p.I269= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV51588655; called by muse, mutect2, varscan2
- USP17L2 | c.198G>A p.K66= | Silent (SNP) | VAF 8/101 reads (8%) | called by muse, mutect2
- VPS51 | c.378G>A p.K126= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV54207294; called by muse, mutect2, varscan2
- ZNF672 | c.1065C>T p.N355= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV60637735; called by muse, mutect2
- ZNF99 | c.*748A>G | 3'UTR (SNP) | VAF 16/55 reads (29%) | catalogued as COSV68055737; called by muse, mutect2, varscan2
